Somatic mutation profile of tumor specimen TCGA-B8-5552-01B (aliquot TCGA-B8-5552-01B-11D-1669-08) from TCGA case TCGA-B8-5552, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.7 years (15,219 days).
Specimen TCGA-B8-5552-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dc5b92b-a85f-4251-aed4-a27e171b600f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5552-10A (Blood Derived Normal), aliquot TCGA-B8-5552-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/011c56ad-3132-4257-ba87-9027eba62107

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, Nonsense Mutation 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIN2 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV57203627; called by muse, mutect2, varscan2
- CHRNB4 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767874808, COSV55714704; called by muse, mutect2, varscan2
- CHRNB4 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.859); catalogued as COSV55714714, COSV99929624; called by muse, mutect2, varscan2
- COPB2 | c.2500A>C p.N834H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV60349056; called by muse, mutect2, varscan2
- DIP2C | c.4271C>A p.T1424N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55146426; called by muse, mutect2, varscan2
- DLD | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52736858; called by muse, mutect2, varscan2
- GPATCH11 | c.124C>T p.Q42* (on ENST00000409774; = p.Q20* on NM_174931.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV51849039, COSV99249589; called by muse, mutect2
- HIPK3 | c.136A>C p.N46H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.625); catalogued as COSV57560902, COSV57563346; called by muse, mutect2, varscan2
- HSP90AA1 | c.2051A>G p.H684R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53487431; called by muse, mutect2, varscan2
- HSPA1L | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs753725330, COSV65148651; called by muse, mutect2, varscan2
- INPP5F | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV62819689; called by muse, mutect2, varscan2
- LCLAT1 | c.417T>A p.Y139* | Nonsense Mutation (SNP) | VAF 43/299 reads (14%) | catalogued as COSV58370373; called by muse, mutect2, varscan2
- MAF | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58153164; called by muse, mutect2, varscan2
- MBP | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.404); catalogued as COSV63556464; called by muse, mutect2, varscan2
- NEK9 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs954321670, COSV53129345; called by muse, mutect2, varscan2
- NEXMIF | c.3536G>T p.S1179I | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV50021999; called by muse, mutect2, varscan2
- NSD1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV61770943; called by muse, mutect2, varscan2
- RFTN1 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV61916873, COSV61917584; called by muse, mutect2, varscan2
- RHBDF1 | c.1831T>C p.S611P | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1385522076, COSV51953556; called by muse, mutect2, varscan2
- SIK2 | c.1502T>A p.I501N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV59250331, COSV59254781; called by muse, mutect2, varscan2
- TBC1D8B | c.3176G>T p.G1059V | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52175977; called by muse, mutect2, varscan2
- TRAPPC11 | c.1049A>T p.Y350F | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV58214605; called by muse, mutect2, varscan2
- XPC | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); catalogued as COSV53203639; called by muse, mutect2, varscan2
- KMT2B | c.5455_5473del p.D1819Mfs*70 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- ADAMTS12 | c.3747C>T p.L1249= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as COSV61255803; called by muse, mutect2, varscan2
- PGAP2 | c.729G>A p.L243= (on ENST00000463452 / NM_001346398.2; = p.L304= on NM_014489.4) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53463946; called by muse, mutect2, varscan2
- PTGIS | c.975G>A p.S325= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs140787750, COSV54834984; called by muse, mutect2, varscan2
- TTN | c.10360+3135T>C | Intron (SNP) | VAF 16/107 reads (15%) | catalogued as COSV59893530; called by muse, mutect2, varscan2
